Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-AA6F, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-AA6F-01A (Primary Tumor).

ICD-O-3

Adenocarcinoma NOS 8140/3

Site: Cardia NOS C16.0

QW 8/20/14

Collect date

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Cardia)

Product of resection of the esophagus and stomach:

- Moderately differentiated adenocarcinoma, ulcerated, located in the cardia, infiltrating the serosa.
- Perineural infiltration present.
- Lymphatic infiltration present.
- Adjacent gastric mucosa with moderate chronic gastritis with lymphoid follicle formation.
- Esophageal mucosa with mild chronic inflammation.
- Surgical margins free of neoplasia.
- Presence of metastasis in 1 of the 14 dissected lymph nodes (1/14).

Criteria	W 12/23/13	Yes	No
H/PA Discrepancy			/

Source: NCI Genomic Data Commons file b4835819-94b3-46f6-9ab5-1de8d04fe433 (TCGA-VQ-AA6F.E312994F-4A15-4634-994E-57C1A26784BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).